Somatic mutation profile of tumor specimen 0DCUL3 from CCDI case PBBKKX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 6.7 years (2,456 days).
Specimen 0DCUL3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bcf54e2-90a2-4d16-ad8f-2d8a3c37255d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCUKR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a84b163-ef33-4861-80a1-c420db4f459c

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 347/1069 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- POLRMT | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.248); called by muse, mutect2
- TMEM272 | c.494T>G p.V165G | Missense Mutation (SNP) | VAF 69/857 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- GAREM1 | c.1338G>A p.P446= | Silent (SNP) | VAF 60/786 reads (8%) | catalogued as rs776614550; called by muse, mutect2
- OSBPL2 | c.741G>A p.L247= (on ENST00000313733 / NM_144498.4; = p.L235= on NM_014835.4) | Silent (SNP) | VAF 87/1049 reads (8%) | called by muse, mutect2
